Somatic mutation profile of tumor specimen TCGA-BQ-5876-01A (aliquot TCGA-BQ-5876-01A-11D-1589-08) from TCGA case TCGA-BQ-5876, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.0 years (27,409 days).
Specimen TCGA-BQ-5876-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee2ac992-c836-473c-a706-8ed3b1c75791.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5876-11A (Solid Tissue Normal), aliquot TCGA-BQ-5876-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92dba03e-b2ed-43de-abea-17f05ea4d90c

The open-access MAF lists 74 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Frame Shift Del 6, Splice Site 3, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYGL | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749922511, COSV53588693; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.4066C>G p.P1356A | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs183308563, COSV61266394, COSV61279109; called by muse, mutect2, varscan2
- AGBL2 | c.1295A>C p.N432T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54095361; called by muse, mutect2, varscan2
- AP4E1 | c.2741T>A p.I914K | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as COSV55920051; called by muse, mutect2, varscan2
- ARHGAP30 | c.1766G>A p.C589Y | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774223470, COSV63519298; called by muse, mutect2
- ASAP2 | c.2579T>C p.L860S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs1487553544, COSV55638529; called by muse, mutect2, varscan2
- ATN1 | c.1337C>A p.P446H | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV63112982; called by muse, mutect2, varscan2
- BIRC6 | c.5647T>C p.Y1883H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as COSV70205728; called by muse, mutect2
- C1orf52 | c.229A>C p.N77H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV53999713; called by muse, mutect2, varscan2
- CHRNB1 | c.916C>G p.P306A | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60142317; called by muse, mutect2, varscan2
- CREG1 | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65148785; called by muse, mutect2, varscan2
- DNTTIP2 | c.662T>G p.I221S | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV63284576; called by muse, mutect2, varscan2
- ENTPD7 | c.1376T>G p.F459C | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65113263; called by muse, mutect2, varscan2
- ERBB4 | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61521988; called by muse, mutect2, varscan2
- FAM71E1 | c.697C>T p.R233C (on ENST00000600100 / NM_001308429.2; = p.R217C on NM_138411.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs774484412, COSV63099821; called by muse, mutect2, varscan2
- FBXO45 | c.549A>T p.Q183H | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1451147947, COSV61147227; called by muse, mutect2, varscan2
- FRS3 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs137923290; called by muse, mutect2, varscan2
- HMCN1 | c.4631-1G>A p.X1544_splice | Splice Site (SNP) | VAF 34/84 reads (40%) | catalogued as COSV54905626, COSV54940446; called by muse, mutect2, varscan2
- HORMAD1 | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV59273177; called by muse, mutect2, varscan2
- IRF2BP1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs759673909, COSV56193977; called by muse, mutect2, varscan2
- LRRC8D | c.779A>T p.K260I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV61581196; called by muse, mutect2, varscan2
- LURAP1L | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59986368; called by muse, mutect2, varscan2
- MAPKBP1 | c.985G>A p.V329I (on ENST00000456763 / NM_001128608.2; = p.V323I on NM_014994.3) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs374717785; called by muse, mutect2, varscan2
- MSH6 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV52287526; called by muse, mutect2, varscan2
- MUC16 | c.8688G>T p.E2896D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV67492745; called by mutect2, varscan2
- NCOA6 | c.4516A>G p.K1506E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV62867789; called by muse, mutect2, varscan2
- OGFRL1 | c.702C>A p.H234Q | Missense Mutation (SNP) | VAF 243/681 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64972512; called by muse, mutect2, varscan2
- OR2A14 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV68718123; called by muse, mutect2, varscan2
- PARP8 | c.2523A>T p.K841N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV55866742; called by muse, mutect2, varscan2
- PCF11 | c.1661A>G p.D554G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV53537556; called by muse, mutect2, varscan2
- PLEKHA6 | c.2483T>C p.M828T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV55340031; called by muse, mutect2
- POMZP3 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.801); catalogued as rs768123787, COSV99300638; called by muse, mutect2, varscan2
- PTPRF | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.146); catalogued as COSV63448779; called by muse, mutect2, varscan2
- RNF216 | c.452T>C p.L151P (on ENST00000425013 / NM_207116.3; = p.L208P on NM_207111.4) | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV66292661; called by muse, mutect2, varscan2
- SHBG | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61412496; called by muse, mutect2, varscan2
- SLC5A3 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62973435; called by muse, mutect2, varscan2
- SLC6A4 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200924626, COSV55568066, COSV55569668; called by muse, mutect2, varscan2
- SPTBN2 | c.3287C>A p.T1096N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV59461220; called by muse, mutect2, varscan2
- SYNE1 | c.12429G>C p.W4143C (on ENST00000367255 / NM_182961.4; = p.W4072C on NM_033071.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV55098387; called by muse, mutect2, varscan2
- TAF1 | c.4605+2T>C p.X1535_splice (on ENST00000373790 / NM_138923.4; = p.X1556_splice on NM_004606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 46/60 reads (77%) | catalogued as COSV52124770; called by muse, mutect2, varscan2
- TCF7L1 | c.1424T>C p.M475T | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as COSV56403242; called by muse, mutect2, varscan2
- TENM1 | c.6173C>G p.T2058S | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV64442784; called by muse, mutect2, varscan2
- TMEM132A | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV50016688, COSV50022321; called by muse, mutect2, varscan2
- TTC7B | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV60639339; called by muse, mutect2, varscan2
- UBP1 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52147750; called by muse, mutect2, varscan2
- ZNF688 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56301949; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2015del p.L672Yfs*26 | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | called by mutect2, pindel, varscan2
- IFNA2 | c.262_265del p.N88Sfs*16 | Frame Shift Del (DEL) | VAF 73/197 reads (37%) | called by mutect2, pindel, varscan2
- MROH1 | c.2325+1del | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- OTOGL | c.4375_4379del p.I1459Cfs*3 (on ENST00000547103; = p.I1450Cfs*3 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, varscan2
- RAB13 | c.481-1_518del p.X161_splice | Splice Site (DEL) | VAF 50/202 reads (25%) | called by mutect2, pindel
- SETD2 | c.5627dup p.M1877Nfs*10 | Frame Shift Ins (INS) | VAF 210/361 reads (58%) | called by mutect2, pindel, varscan2
- SMARCB1 | c.707del p.D236Afs*14 (on ENST00000263121; = p.D282Afs*14 on NM_003073.5) | Frame Shift Del (DEL) | VAF 48/82 reads (59%) | called by mutect2, pindel, varscan2
- SPEF2 | c.3838_3840del p.E1280del | In Frame Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- TRIM41 | c.1351dup p.R451Pfs*14 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- WDR33 | c.827del p.K276Rfs*16 | Frame Shift Del (DEL) | VAF 36/131 reads (27%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.7401A>T p.T2467= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV67995158; called by muse, mutect2, varscan2
- CCDC88A | c.1377A>C p.S459= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV55069829; called by muse, mutect2, varscan2
- CENPM | c.102G>C p.S34= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV53245905; called by muse, mutect2, varscan2
- CRIP3 | c.318A>G p.Q106= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs568254475, COSV51486072; called by muse, mutect2, varscan2
- CXCR4 | c.117C>A p.I39= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV54011081, COSV54013124; called by muse, mutect2, varscan2
- DNAH7 | c.5751A>G p.Q1917= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs941455284, COSV56785431; called by muse, mutect2
- DPF2 | c.699G>A p.L233= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV52891315; called by muse, mutect2, varscan2
- EIF5B | c.3537A>C p.T1179= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV51490361; called by muse, mutect2, varscan2
- MYO10 | c.1206C>A p.A402= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV72563032, COSV72563534; called by muse, mutect2, varscan2
- PCDHGC4 | c.585C>G p.L195= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV52767773; called by muse, mutect2, varscan2
- PIAS1 | c.1782T>C p.S594= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV51037786; called by muse, mutect2, varscan2
- PITPNM2 | c.2031G>A p.Q677= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV54908721; called by muse, mutect2, varscan2
- SASS6 | c.1362T>G p.V454= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54930383; called by muse, mutect2, varscan2
- SLC16A13 | c.1077C>G p.L359= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV57275074; called by muse, mutect2
- TRAV8-4 | c.51A>C p.G17= | Silent (SNP) | VAF 41/62 reads (66%) | called by muse, mutect2, varscan2
- VPS13D | c.1695T>C p.T565= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV62534243; called by muse, mutect2, varscan2
- POMGNT1 | c.*434C>A | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as COSV64340914; called by muse, mutect2, varscan2
- TEX2 | chr17:64146420 C>A | 3'Flank (SNP) | VAF 72/197 reads (37%) | called by muse, mutect2, varscan2
